RC case RC-B6E4 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d04914a8-5509-4352-bff2-4de844526bb4

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1962; Vital status: Alive.

Diagnoses (1)
1. Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants): ICD-O-3 morphology code: 9827/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 58.3 years (21,277 days); Year of diagnosis: 2020; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Interferon + Zidovudine; Initial disease status: Initial Diagnosis; Days to treatment start: 27 days; Days to treatment end: 83 days; Treatment outcome: Treatment Stopped Due to Toxicity; Reason treatment ended: Adverse Event; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial Agent; Initial disease status: Initial Diagnosis; Days to treatment start: 136 days; Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (3 entries)
- Days to follow up: 245 days; Disease response: Tumor Free.
- Day 473 (end of treatment course 1): Disease response: Tumor Free.
- Days to follow up: 781 days (2.1 years); Disease response: Tumor Free.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Rectal Cancer.

Biospecimens (3 samples)
- Sample RC-B6E4-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Samples RC-B6E4-TBP1-A, RC-B6E4-TBP1-B (2 with the same recorded description): Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
